Somatic mutation profile of tumor specimen CDDP-ABLL-TTP1-B (aliquot CDDP-ABLL-TTP1-B-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABLL, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68 years.
Specimen CDDP-ABLL-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dacf800c-67e7-4c4c-9c2c-1ab820f45dd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABLL-NB1-A (Blood Derived Normal), aliquot CDDP-ABLL-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f3d8d71-d695-419a-9f4e-278832c8675d

The open-access MAF lists 492 somatic variants for this specimen: 329 protein-altering or splice-affecting, 100 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 100, Intron 24, Nonsense Mutation 19, RNA 16, Splice Site 9, 3'UTR 9, Frame Shift Del 8, 5'UTR 7, 5'Flank 5, Frame Shift Ins 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 124/359 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYBPC3 | c.2541C>A p.Y847* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | catalogued as rs397515974, CM043545, COSV99920990, COSV99921105; ClinVar: pathogenic; called by muse, varscan2
- ABCG8 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 127/755 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968485818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI2 | c.1118G>T p.R373L (on ENST00000295851 / NM_001375719.1; = p.R306L on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53689816; called by muse, mutect2, varscan2
- ADAMTS16 | c.3606G>T p.Q1202H | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56983858; called by muse, mutect2
- ADCY10 | c.4423C>T p.Q1475* | Nonsense Mutation (SNP) | VAF 61/320 reads (19%) | catalogued as COSV63239141; called by muse, mutect2, varscan2
- ADGRE1 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs745484883; called by muse, mutect2, varscan2
- ALDOB | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.721); catalogued as rs1405680272, COSV66397550; called by muse, mutect2, varscan2
- ALK | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs762635291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKS1B | c.2149G>T p.G717W | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100243789; called by muse, mutect2, varscan2
- ARMH4 | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 38/246 reads (15%) | catalogued as rs375790812; called by muse, mutect2, varscan2
- ASGR2 | c.835_836del p.V279* | Frame Shift Del (DEL) | VAF 35/201 reads (17%) | catalogued as rs754263063; called by pindel, varscan2
- ATM | c.7462T>C p.C2488R | Missense Mutation (SNP) | VAF 103/344 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1555123216, CM053098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AURKAIP1 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366506763, COSV100408695; called by muse, mutect2, varscan2
- C1orf94 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV64914468; called by muse, mutect2, varscan2
- CBFA2T3 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); catalogued as rs770164863, COSV51922556; called by muse, mutect2, varscan2
- CCDC125 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV67289109; called by muse, mutect2, varscan2
- CELSR1 | c.6791C>T p.P2264L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs745998249; called by muse, mutect2, varscan2
- CFAP61 | c.2870A>T p.Y957F | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0.085); catalogued as rs200499872; called by muse, mutect2, varscan2
- CHRM2 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1455067791, COSV57774807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.2480A>G p.K827R | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV56713795; called by muse, mutect2, varscan2
- CSMD3 | c.4624G>T p.D1542Y (on ENST00000297405 / NM_001363185.1; = p.D1438Y on NM_052900.3) | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52349455; called by muse, mutect2, varscan2
- CYP3A43 | c.52A>G p.S18G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1283809918; called by muse, mutect2, varscan2
- DDN | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as rs764084891; called by muse, mutect2, varscan2
- DDN | c.1332G>T p.Q444H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs751744570; called by muse, mutect2, varscan2
- DDX53 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100028658; called by muse, mutect2, varscan2
- DLGAP2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769043986, COSV101421993; called by muse, mutect2, varscan2
- DNAH11 | c.3719A>G p.H1240R | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs535524168; called by muse, mutect2, varscan2
- DNAH7 | c.9926G>C p.G3309A | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56763980; called by muse, mutect2, varscan2
- DYNC2LI1 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs763733041; called by muse, mutect2, varscan2
- FAM184A | c.1585C>G p.Q529E | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV58858711; called by muse, mutect2, varscan2
- FLG | c.7324C>A p.H2442N | Missense Mutation (SNP) | VAF 310/834 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV64242133; called by muse, mutect2, varscan2
- FOLH1 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900061825, COSV57045648; called by muse, mutect2
- FPR1 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 123/454 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs201541948; called by muse, mutect2, varscan2
- GRM5 | c.1388del p.P463Qfs*6 | Frame Shift Del (DEL) | VAF 52/186 reads (28%) | catalogued as COSV59589804; called by mutect2, pindel
- GUCY1A2 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.527); catalogued as rs186283289; called by muse, varscan2
- HCN1 | c.2027G>C p.S676T | Missense Mutation (SNP) | VAF 212/482 reads (44%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV57521709; called by muse, mutect2, varscan2
- IGKV3D-20 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.722); catalogued as rs1553485011; called by muse, varscan2
- INPPL1 | c.3375G>T p.Q1125H | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.969); catalogued as COSV53359943; called by muse, mutect2, varscan2
- IPO9 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 81/708 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs954588982; called by muse, mutect2, varscan2
- KCNA5 | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 222/645 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV52908632; called by muse, mutect2, varscan2
- KCNB2 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV101578785; called by muse, mutect2, varscan2
- KEL | c.1726G>T p.G576C | Missense Mutation (SNP) | VAF 83/365 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201778033, CM1412779; called by muse, mutect2, varscan2
- KIF1A | c.108C>A p.T36= | Splice Region (SNP) | VAF 17/134 reads (13%) | catalogued as COSV100240857; called by muse, mutect2, varscan2
- KIF21B | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 155/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163495836; called by muse, mutect2, varscan2
- KRT17 | c.769C>A p.R257S | Missense Mutation (SNP) | VAF 77/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60860308; called by muse, mutect2, varscan2
- LAMB4 | c.1778G>A p.W593* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV52729768; called by muse, mutect2, varscan2
- LILRB3 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs199861387; called by muse, mutect2, varscan2
- LINGO2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs371555423; called by muse, mutect2, varscan2
- LLGL2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs138074005; called by muse, mutect2, varscan2
- LRFN5 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769433757; called by muse, mutect2, varscan2
- LRP2 | c.3889G>T p.G1297W | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs771733361, COSV99787459; called by muse, mutect2, varscan2
- MAP1A | c.7910C>T p.A2637V | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1566979676; called by muse, mutect2, varscan2
- MARCO | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59051526; called by muse, mutect2, varscan2
- MMP1 | c.929C>A p.P310Q | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as COSV59511948; called by muse, mutect2, varscan2
- MMP16 | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1331980989; called by muse, mutect2
- MPND | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53658964; called by muse, mutect2, varscan2
- MS4A6A | c.339+1G>T p.X113_splice | Splice Site (SNP) | VAF 19/140 reads (14%) | catalogued as rs762302880; called by muse, mutect2, varscan2
- MUC16 | c.43242G>T p.M14414I | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV101109806; called by muse, mutect2, varscan2
- MXRA5 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs774336219; called by muse, mutect2, varscan2
- MYH11 | c.4712C>A p.A1571E | Missense Mutation (SNP) | VAF 86/687 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55556716; called by muse, mutect2, varscan2
- MYO16 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs774460438; called by muse, mutect2, varscan2
- MYO3A | c.4453G>T p.E1485* | Nonsense Mutation (SNP) | VAF 59/210 reads (28%) | catalogued as COSV99781439; called by muse, mutect2, varscan2
- NHLRC1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 166/728 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV61481886; called by muse, mutect2, varscan2
- NINL | c.2498G>A p.G833E | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as rs1162595811; called by muse, mutect2, varscan2
- NOL4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 52/357 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.569); catalogued as COSV99307638; called by muse, mutect2, varscan2
- OBP2A | c.222C>A p.C74* | Nonsense Mutation (SNP) | VAF 45/243 reads (19%) | catalogued as rs1257458042; called by muse, mutect2, varscan2
- OLIG3 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 73/354 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV62988761; called by muse, mutect2, varscan2
- OR10D3 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1399550197; called by muse, mutect2, varscan2
- OR10R2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV63768790; called by muse, mutect2, varscan2
- OR4K2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895680210; called by muse, mutect2, varscan2
- OR51I1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1198746419; called by muse, mutect2, varscan2
- OR8K5 | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57887745; called by muse, mutect2, varscan2
- OTOF | c.5159C>A p.T1720K (on ENST00000272371 / NM_194248.3; = p.T953K on NM_004802.4) | Missense Mutation (SNP) | VAF 80/488 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV55506795; called by muse, mutect2, varscan2
- PAPPA2 | c.1931G>T p.C644F | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62782972; called by muse, mutect2, varscan2
- PARVG | c.216G>T p.M72I | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1366367677, COSV63562546; called by muse, mutect2, varscan2
- PCDH10 | c.939C>A p.S313R | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs769286962, COSV99993129; called by muse, mutect2, varscan2
- PCDHB7 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs546236115, COSV50755630; called by muse, mutect2, varscan2
- PCDHGA2 | c.1344C>A p.N448K | Missense Mutation (SNP) | VAF 105/266 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53909517; called by muse, mutect2, varscan2
- PGBD1 | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); catalogued as COSV52551322, COSV52551801; called by muse, mutect2, varscan2
- POU2F1 | c.1577C>T p.P526L (on ENST00000541643 / NM_001365848.1; = p.P549L on NM_002697.4) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV54816217; called by muse, mutect2, varscan2
- PPP3CA | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | catalogued as COSV59921283; called by muse, mutect2, varscan2
- PRDM9 | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 100/553 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99690369, COSV99690464; called by muse, mutect2, varscan2
- QRFPR | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV57677919; called by muse, mutect2, varscan2
- RAG1 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); catalogued as COSV55024832; called by muse, mutect2, varscan2
- RASGRF2 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54127118; called by muse, mutect2, varscan2
- ROPN1L | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99928571; called by muse, mutect2, varscan2
- RYR2 | c.7301G>A p.G2434D | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763374997; called by muse, mutect2, varscan2
- SEPTIN14 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66426480, COSV66429007; called by muse, mutect2, varscan2
- SERPINC1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs374205395, CD961789; called by muse, mutect2, varscan2
- SEZ6L | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs773941150, COSV50666514; called by muse, mutect2, varscan2
- SHC4 | c.691G>T p.G231W | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202001880; called by muse, mutect2, varscan2
- SHCBP1L | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1340560682, COSV62354984; called by muse, mutect2, varscan2
- SLC17A6 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV99580538; called by muse, mutect2, varscan2
- SLC32A1 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54147005; called by muse, mutect2, varscan2
- SLC44A5 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63776118; called by muse, mutect2, varscan2
- SLITRK2 | c.1717G>T p.G573W | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100157920, COSV59424402; called by muse, mutect2
- SNTG1 | c.1246T>A p.F416I | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99384142; called by muse, mutect2
- SPATA31A6 | c.1004C>A p.T335K | Missense Mutation (SNP) | VAF 283/846 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs776783154; called by muse, mutect2, varscan2
- TCOF1 | c.1319C>T p.S440L (on ENST00000377797 / NM_001135243.1; = p.S363L on NM_000356.4) | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs768338173, COSV60348479; called by muse, mutect2, varscan2
- TENM2 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs752353786, COSV72852991; called by muse, mutect2, varscan2
- TENM3 | c.6374C>A p.T2125N | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1307785003; called by muse, mutect2, varscan2
- TEPSIN | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56142459; called by muse, mutect2, varscan2
- TGIF2LX | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV99383256; called by muse, mutect2, varscan2
- TIGD4 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100428079; called by muse, mutect2, varscan2
- TNNI3 | c.422G>C p.R141P | Missense Mutation (SNP) | VAF 118/420 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM031378, COSV52573447; called by muse, mutect2, varscan2
- TRIM42 | c.963C>G p.H321Q | Missense Mutation (SNP) | VAF 100/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973883247, COSV53880614; called by muse, mutect2, varscan2
- TRIM58 | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV63569529; called by muse, mutect2
- TTN | c.79844C>G p.P26615R (on ENST00000591111; = p.P19191R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | PolyPhen probably damaging (0.999); catalogued as rs1471654311; called by muse, mutect2, varscan2
- TUT4 | c.1388+1G>T p.X463_splice | Splice Site (SNP) | VAF 9/87 reads (10%) | catalogued as COSV57119777; called by muse, mutect2, varscan2
- TYROBP | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 46/542 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs370767403, COSV99385540; called by muse, mutect2
- VWA3A | c.2817G>T p.Q939H | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV55393323; called by muse, mutect2, varscan2
- XIRP2 | c.841C>A p.P281T (on ENST00000628543; = p.P456T on NM_152381.6) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs751995720, COSV54709775; called by muse, mutect2, varscan2
- YBX1 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1310375389; called by muse, mutect2
- ZNF423 | c.2491G>T p.E831* (on ENST00000563137 / NM_001379286.1; = p.E823* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 46/242 reads (19%) | catalogued as rs1555515076, COSV52193203; called by muse, mutect2, varscan2
- ZNF474 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99682062; called by muse, mutect2, varscan2
- ZNF536 | c.2754G>C p.L918F | Missense Mutation (SNP) | VAF 123/398 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs188702446; called by muse, mutect2, varscan2
- AASDH | c.2383A>T p.K795* | Nonsense Mutation (SNP) | VAF 72/209 reads (34%) | called by muse, mutect2, varscan2
- ABCC1 | c.2408G>T p.G803V | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC12 | c.2870G>T p.S957I | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC8 | c.1203C>A p.H401Q | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY2 | c.1218G>A p.W406* | Nonsense Mutation (SNP) | VAF 152/293 reads (52%) | called by muse, mutect2, varscan2
- ADGRL2 | c.4127C>T p.P1376L (on ENST00000370717 / NM_001366005.1; = p.P1320L on NM_012302.4) | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- ADGRL3 | c.3373T>A p.S1125T (on ENST00000506720 / NM_001322402.2; = p.S1057T on NM_015236.6) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ALK | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 105/587 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ANKRD26 | c.1629G>T p.Q543H | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD27 | c.2178G>T p.R726S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ANO10 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGEF10L | c.3341G>T p.G1114V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ASPG | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ASTN1 | c.3303C>A p.D1101E | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ASTN1 | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ATP1A1 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BFSP1 | c.1414_1415dup p.V473Wfs*50 | Frame Shift Ins (INS) | VAF 41/265 reads (15%) | called by mutect2, pindel, varscan2
- CABS1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA2D4 | c.1351+3G>C | Splice Region (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- CCN4 | c.539G>A p.C180Y | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT4 | c.1403A>T p.N468I | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDIN1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CDX4 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CEP83 | c.253C>A p.Q85K | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CERS4 | c.848A>T p.Q283L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CHRNA1 | c.799T>A p.C267S (on ENST00000261007 / NM_001039523.3; = p.C242S on NM_000079.4) | Missense Mutation (SNP) | VAF 123/475 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- CLIP4 | c.778A>G p.N260D | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL11A1 | c.2236del p.A746Lfs*19 | Frame Shift Del (DEL) | VAF 28/156 reads (18%) | called by mutect2, pindel, varscan2
- COL2A1 | c.2005G>C p.G669R | Missense Mutation (SNP) | VAF 180/578 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- COL6A3 | c.7488G>T p.R2496S | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- COL6A3 | c.7487G>T p.R2496M | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL9A3 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 168/549 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COLEC11 | c.29T>A p.V10D | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPD | c.3085A>T p.R1029W | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPS1 | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CSMD1 | c.5908C>A p.L1970M (on ENST00000520002; = p.L1969M on NM_033225.6) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP2B6 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 110/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2B6 | c.1059C>G p.I353M | Missense Mutation (SNP) | VAF 114/488 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- DCDC1 | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DECR1 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- DIDO1 | c.6369G>T p.W2123C | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DNAH14 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- DOCK7 | c.1215A>T p.L405F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPP10 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DSCAM | c.2220T>A p.N740K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- EGLN2 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- EIF2S3B | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 82/600 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPB41 | c.1338C>A p.S446R (on ENST00000343067 / NM_001166005.2; = p.S237R on NM_004437.4) | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ERP44 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, varscan2
- FANCA | c.1724G>T p.R575M | Missense Mutation (SNP) | VAF 135/630 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.3556A>T p.I1186F | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FCHO2 | c.17T>G p.F6C | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- FFAR1 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 49/417 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- FRMD6 | c.715-1G>T p.X239_splice (on ENST00000344768 / NM_001267046.2; = p.X231_splice on NM_152330.4) | Splice Site (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- GABRA1 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GAD2 | c.1255A>T p.N419Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, varscan2
- GFRAL | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNAO1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.619); called by muse, varscan2
- GOLGA8J | c.1067G>T p.R356M | Missense Mutation (SNP) | VAF 227/683 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GPHN | c.173T>G p.I58R | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- GPX4 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK1 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GTF2IRD1 | c.2221G>T p.V741L (on ENST00000265755 / NM_016328.3; = p.V726L on NM_005685.4) | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- GTF3C1 | c.5911G>T p.A1971S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- H1-4 | c.548dup p.A184Gfs*12 | Frame Shift Ins (INS) | VAF 67/599 reads (11%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.2181G>T p.Q727H | Missense Mutation (SNP) | VAF 91/314 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HNRNPM | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.899); called by muse, varscan2
- HOXA9 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HPRT1 | c.319-6_319-1delinsTTTTAA p.X107_splice | Splice Site (ONP) | VAF 7/61 reads (11%) | called by muse*, pindel
- HS3ST3A1 | c.1146G>T p.R382S | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- IFT88 | c.1355A>G p.K452R (on ENST00000319980 / NM_001318493.2; = p.K443R on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INSC | c.556C>A p.L186I | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.741); called by mutect2, varscan2
- IQSEC1 | c.1882A>T p.I628L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IRX5 | c.1240A>C p.N414H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ITGA2 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ITGAD | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 58/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- JPH3 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KAT6A | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNC2 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- KCNJ12 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 178/1127 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- KCNJ16 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 65/252 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KIAA1549L | c.3772C>A p.L1258M (on ENST00000321505; = p.L1555M on NM_012194.3) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- KMT2B | c.1610C>G p.S537C | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KRT71 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMB4 | c.1779G>T p.W593C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARS1 | c.868G>T p.V290L (on ENST00000394434 / NM_020117.11; = p.V263L on NM_016460.3) | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRBA | c.7193A>T p.K2398I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LRP1B | c.6011A>T p.H2004L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, varscan2
- MAGEB18 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MEFV | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 113/697 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- METTL3 | c.10A>T p.T4S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2
- MMP16 | c.387C>A p.H129Q | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2
- MS4A6A | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MUC17 | c.7256C>A p.T2419K | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVK | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MXRA5 | c.7172C>A p.S2391Y | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYBL1 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- MYF6 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MYH8 | c.3928G>T p.A1310S | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO3A | c.797+1G>T p.X266_splice | Splice Site (SNP) | VAF 36/191 reads (19%) | called by muse, mutect2, varscan2
- NANOGNB | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NDST4 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NF1 | c.7074A>T p.E2358D (on ENST00000358273 / NM_001042492.3; = p.E2337D on NM_000267.3) | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NHLH1 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 170/521 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLRP14 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NLRP4 | c.1032C>A p.C344* | Nonsense Mutation (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- NOS1 | c.3471G>T p.E1157D | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NPY1R | c.807_809del p.V270del | In Frame Del (DEL) | VAF 27/182 reads (15%) | called by mutect2, pindel, varscan2
- OBI1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OCLN | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OPA3 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 39/434 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); called by muse, mutect2
- OR10A2 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- OR10A5 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR14K1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2A1 | c.307T>A p.C103S | Missense Mutation (SNP) | VAF 100/783 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2G2 | c.437C>A p.A146D | Missense Mutation (SNP) | VAF 177/337 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- OR51B6 | c.744del p.F249Sfs*5 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | called by mutect2, pindel, varscan2
- OR5B3 | c.568A>T p.R190* | Nonsense Mutation (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- OR6C2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- OR8I2 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.929); called by muse, mutect2
- OR9G1 | c.422C>A p.A141E | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.189); called by muse, mutect2
- OSMR | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 84/161 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPSS1 | c.731T>A p.L244H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PASD1 | c.1448T>G p.V483G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- PAX6 | c.263C>G p.A88G | Missense Mutation (SNP) | VAF 151/588 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PBXIP1 | c.1682G>T p.R561M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- PCDH15 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT tolerated, low confidence (0.1); called by muse, mutect2, varscan2
- PCDH17 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX2 | c.2784G>C p.R928S | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PCSK6 | c.823+1G>T p.X275_splice | Splice Site (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- PHF24 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIEZO2 | c.7441-2del p.X2481_splice | Splice Site (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel*, varscan2
- PKD1L1 | c.6154G>C p.D2052H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PKD1L1 | c.1445A>G p.N482S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PKDREJ | c.5741T>A p.V1914E | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLPPR4 | c.1185dup p.V396Cfs*59 | Frame Shift Ins (INS) | VAF 42/216 reads (19%) | called by mutect2, pindel, varscan2
- PLXDC2 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PLXNA4 | c.3998C>A p.P1333H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.3997C>A p.P1333T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POM121L12 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 136/538 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PPP3R2 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRR19 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PRSS1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, varscan2
- PRSS22 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- PTPRD | c.3908G>C p.S1303T | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PYY | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REG4 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RFPL4A | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 27/498 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2
- RHAG | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPN2 | c.303+1G>T p.X101_splice | Splice Site (SNP) | VAF 120/403 reads (30%) | called by muse, mutect2, varscan2
- RPN2 | c.1296C>G p.H432Q | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RRH | c.398-1G>T p.X133_splice | Splice Site (SNP) | VAF 70/275 reads (25%) | called by muse, mutect2, varscan2
- RTTN | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- RUFY3 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 46/148 reads (31%) | called by muse, mutect2, varscan2
- RYR2 | c.5328C>A p.Y1776* | Nonsense Mutation (SNP) | VAF 178/436 reads (41%) | called by muse, mutect2, varscan2
- S100Z | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2
- SALL3 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SBSN | c.1031G>T p.W344L | Missense Mutation (SNP) | VAF 160/477 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCARF1 | c.1520A>G p.H507R | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SETBP1 | c.3615del p.K1205Nfs*47 | Frame Shift Del (DEL) | VAF 109/660 reads (17%) | called by mutect2, pindel, varscan2
- SI | c.2767del p.G924Efs*72 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- SLC30A1 | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SLC35G2 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SLC4A2 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLITRK2 | c.1715T>G p.L572R | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- SMC4 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNAPC4 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2
- SNRNP35 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPATA31A6 | c.3466G>A p.V1156I | Missense Mutation (SNP) | VAF 309/801 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA31A6 | c.3679A>T p.K1227* | Nonsense Mutation (SNP) | VAF 202/967 reads (21%) | called by muse, mutect2, varscan2
- SPEF1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SULF1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 22/467 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- TAS2R41 | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBC1D31 | c.654A>T p.K218N | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TDRD6 | c.5309A>C p.D1770A | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TEX15 | c.5947C>G p.H1983D (on ENST00000256246; = p.H2366D on NM_001350162.2) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TIAM1 | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 143/320 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.077); called by muse, mutect2
- TIAM1 | c.376A>C p.M126L | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); called by muse, mutect2
- TINAG | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TLL2 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TMED10 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM132B | c.2452A>G p.I818V | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM132E | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TMEM150B | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TMTC4 | c.922G>T p.A308S (on ENST00000376234 / NM_001350577.2; = p.A327S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TOGARAM2 | c.1258A>G p.R420G | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TRAPPC8 | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV27 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- TRPA1 | c.3032G>T p.R1011I | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TRPS1 | c.905T>A p.L302Q (on ENST00000220888 / NM_001330599.2; = p.L315Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TTN | c.20306G>A p.S6769N (on ENST00000591111; = p.S5842N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- UBTFL1 | c.766A>T p.R256* | Nonsense Mutation (SNP) | VAF 31/227 reads (14%) | called by mutect2, varscan2
- UNC80 | c.9348G>T p.Q3116H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- URGCP | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2
- USO1 | c.2366A>T p.E789V | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- USP29 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- WDR17 | c.847A>T p.M283L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.152); called by muse, varscan2
- WDR26 | c.1203A>T p.L401F (on ENST00000414423 / NM_001379403.1; = p.L301F on NM_025160.7) | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WNT9B | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 121/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- XKR4 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- ZEB2 | c.2875C>A p.Q959K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZFP69 | c.843_846del p.K281Nfs*9 | Frame Shift Del (DEL) | VAF 54/256 reads (21%) | called by mutect2, pindel, varscan2
- ZNF319 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF418 | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF470 | c.971T>A p.L324H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF574 | c.2250G>T p.E750D | Missense Mutation (SNP) | VAF 90/273 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF724 | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804A | c.44A>T p.N15I | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ZNF804A | c.543del p.T182Lfs*43 | Frame Shift Del (DEL) | VAF 35/145 reads (24%) | called by mutect2, pindel, varscan2
- ZNF879 | c.872A>T p.K291M | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- ACACA | c.3195C>T p.I1065= | Silent (SNP) | VAF 38/222 reads (17%) | called by muse, mutect2, varscan2
- ACSF3 | c.372C>T p.P124= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2
- ACSM1 | c.90G>T p.R30= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ADGRG2 | c.912C>A p.P304= (on ENST00000379869 / NM_001079858.3; = p.P301= on NM_005756.4) | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV61341938; called by muse, mutect2, varscan2
- ADRA1A | c.393G>A p.P131= | Silent (SNP) | VAF 43/220 reads (20%) | catalogued as rs763776846; called by muse, mutect2, varscan2
- ANPEP | c.2256C>T p.S752= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as rs760292696; called by muse, mutect2, varscan2
- ASPM | c.1560T>C p.C520= | Silent (SNP) | VAF 164/306 reads (54%) | catalogued as rs1372835902; called by muse, mutect2, varscan2
- ATIC | c.1035A>T p.G345= | Silent (SNP) | VAF 16/251 reads (6%) | catalogued as COSV52691522; called by muse, mutect2
- ATP4B | c.534T>C p.C178= | Silent (SNP) | VAF 100/222 reads (45%) | called by muse, mutect2, varscan2
- C2CD2L | c.1428G>A p.E476= | Silent (SNP) | VAF 59/160 reads (37%) | catalogued as rs1162004973; called by muse, mutect2, varscan2
- CCDC27 | c.235C>A p.R79= | Silent (SNP) | VAF 77/327 reads (24%) | catalogued as rs202157664, COSV53902473; called by muse, mutect2, varscan2
- CERKL | c.879A>T p.P293= (on ENST00000339098 / NM_001030311.2; = p.P267= on NM_201548.5) | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- CFAP46 | c.5877C>T p.A1959= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs369370126; called by muse, mutect2
- CGN | c.543C>G p.L181= | Silent (SNP) | VAF 90/701 reads (13%) | called by muse, mutect2, varscan2
- CHRM2 | c.1335C>A p.A445= | Silent (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- CHRNA3 | c.933C>A p.T311= | Silent (SNP) | VAF 129/311 reads (41%) | called by muse, mutect2, varscan2
- CLCN3 | c.207A>T p.T69= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs553523589; called by muse, mutect2, varscan2
- CLDN3 | c.234G>C p.A78= | Silent (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.312G>A p.T104= | Silent (SNP) | VAF 17/174 reads (10%) | catalogued as rs747133475, COSV70484511; called by muse, mutect2
- COL15A1 | c.1443C>A p.V481= | Silent (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- COL6A6 | c.1335G>C p.G445= | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV62037067; called by muse, mutect2, varscan2
- CSAG3 | c.252A>T p.P84= | Silent (SNP) | VAF 61/513 reads (12%) | called by muse, mutect2, varscan2
- CSF2RB | c.2379C>T p.V793= | Silent (SNP) | VAF 52/233 reads (22%) | catalogued as rs139026228; called by muse, mutect2, varscan2
- CSMD3 | c.7800C>T p.F2600= (on ENST00000297405 / NM_001363185.1; = p.F2496= on NM_052900.3) | Silent (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- CYP3A43 | c.51C>A p.T17= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.373C>A p.R125= | Silent (SNP) | VAF 68/607 reads (11%) | catalogued as COSV60476386, COSV60476821; called by muse, mutect2, varscan2
- DEFA5 | c.141A>T p.A47= | Silent (SNP) | VAF 30/121 reads (25%) | called by muse, mutect2, varscan2
- DPP10 | c.663A>T p.I221= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- E2F7 | c.1683G>T p.L561= | Silent (SNP) | VAF 123/591 reads (21%) | catalogued as rs1212793935; called by muse, mutect2, varscan2
- EFHD1 | c.672G>T p.R224= | Silent (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.1050C>T p.N350= | Silent (SNP) | VAF 33/146 reads (23%) | called by muse, varscan2
- EIF2S3B | c.1242A>G p.G414= | Silent (SNP) | VAF 78/605 reads (13%) | called by muse, mutect2
- EIF3H | c.981C>T p.C327= | Silent (SNP) | VAF 32/256 reads (13%) | catalogued as rs759668688; called by muse, mutect2, varscan2
- EYS | c.6105T>C p.T2035= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- F13A1 | c.750C>A p.L250= | Silent (SNP) | VAF 67/368 reads (18%) | called by muse, mutect2, varscan2
- FAF1 | c.1167G>T p.V389= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1881A>T p.P627= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- FANK1 | c.501C>A p.G167= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- GPR180 | c.333G>A p.L111= | Silent (SNP) | VAF 39/128 reads (30%) | called by muse, mutect2, varscan2
- GPR45 | c.324C>G p.R108= | Silent (SNP) | VAF 139/664 reads (21%) | called by muse, mutect2, varscan2
- GRIN2A | c.3531G>A p.G1177= | Silent (SNP) | VAF 70/244 reads (29%) | called by muse, mutect2, varscan2
- GRIN2D | c.738C>G p.L246= | Silent (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- HAND2 | c.276G>T p.L92= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs542409297, COSV100854233, COSV64018267; called by muse, mutect2, varscan2
- HIVEP2 | c.4023C>T p.H1341= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as rs377147535; called by muse, mutect2, varscan2
- IBA57 | c.201G>C p.A67= | Silent (SNP) | VAF 131/276 reads (47%) | catalogued as rs934566495; called by muse, mutect2, varscan2
- IGSF3 | c.3327A>T p.L1109= (on ENST00000369486 / NM_001007237.3; = p.L1129= on NM_001542.4) | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ILDR2 | c.1167A>T p.S389= | Silent (SNP) | VAF 53/492 reads (11%) | called by muse, mutect2, varscan2
- INTS1 | c.1752C>T p.A584= | Silent (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- IRX5 | c.1239G>T p.T413= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV58058729; called by muse, mutect2
- ITGA8 | c.1773T>C p.T591= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- KCNS1 | c.1365C>T p.I455= | Silent (SNP) | VAF 61/265 reads (23%) | called by muse, mutect2, varscan2
- KNDC1 | c.2025G>T p.T675= | Silent (SNP) | VAF 112/268 reads (42%) | catalogued as COSV58832109; called by muse, mutect2, varscan2
- KRT3 | c.243G>T p.G81= | Silent (SNP) | VAF 74/491 reads (15%) | called by muse, mutect2, varscan2
- KRT33A | c.1176A>T p.L392= | Silent (SNP) | VAF 36/242 reads (15%) | catalogued as rs908745872; called by muse, mutect2, varscan2
- KRTAP13-2 | c.282G>T p.T94= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as COSV67762032; called by muse, mutect2, varscan2
- LAMA1 | c.3975G>T p.S1325= | Silent (SNP) | VAF 63/411 reads (15%) | called by muse, mutect2, varscan2
- LGALS13 | c.75A>C p.T25= | Silent (SNP) | VAF 132/413 reads (32%) | called by muse, mutect2, varscan2
- MAPK15 | c.882C>T p.S294= | Silent (SNP) | VAF 48/326 reads (15%) | catalogued as rs781933381; called by muse, mutect2, varscan2
- MCHR2 | c.987C>A p.I329= | Silent (SNP) | VAF 36/182 reads (20%) | called by muse, varscan2
- MRM1 | c.690A>G p.T230= | Silent (SNP) | VAF 66/220 reads (30%) | called by muse, mutect2, varscan2
- MXRA5 | c.6873G>T p.S2291= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV54228545; called by muse, mutect2, varscan2
- MYO10 | c.2043C>T p.D681= | Silent (SNP) | VAF 90/402 reads (22%) | catalogued as rs1338707973; called by muse, varscan2
- NANOGNB | c.9G>T p.R3= | Silent (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- NOTUM | c.846G>A p.T282= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as COSV68825717; called by muse, mutect2, varscan2
- NPFFR2 | c.1023T>C p.Y341= | Silent (SNP) | VAF 34/257 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.258C>T p.G86= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV101277460; called by muse, mutect2
- OR2B11 | c.588C>G p.T196= | Silent (SNP) | VAF 133/224 reads (59%) | called by muse, mutect2, varscan2
- OR2T12 | c.267C>G p.A89= | Silent (SNP) | VAF 256/522 reads (49%) | called by muse, mutect2, varscan2
- OR2T2 | c.618G>T p.L206= | Silent (SNP) | VAF 196/442 reads (44%) | called by mutect2, varscan2
- OR5D16 | c.798C>A p.S266= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV101004125; called by muse, varscan2
- OR7G3 | c.726G>T p.G242= | Silent (SNP) | VAF 139/335 reads (41%) | called by muse, mutect2, varscan2
- OTUD7B | c.1491G>A p.K497= | Silent (SNP) | VAF 103/341 reads (30%) | called by muse, mutect2, varscan2
- PAGE2B | c.81G>C p.V27= | Silent (SNP) | VAF 48/76 reads (63%) | called by muse, mutect2, varscan2
- PCDH15 | c.5022G>A p.E1674= | Silent (SNP) | VAF 90/241 reads (37%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1257C>T p.I419= | Silent (SNP) | VAF 259/641 reads (40%) | called by muse, mutect2, varscan2
- PDHA2 | c.120T>C p.D40= | Silent (SNP) | VAF 54/213 reads (25%) | catalogued as rs778311490; called by muse, mutect2, varscan2
- REN | c.1041C>T p.S347= | Silent (SNP) | VAF 259/553 reads (47%) | catalogued as rs1257300615, COSV65817237; called by muse, mutect2, varscan2
- RORC | c.255C>T p.H85= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs777188216; called by muse, mutect2, varscan2
- RPL7A | c.378G>T p.G126= | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- RXRG | c.1155C>T p.S385= | Silent (SNP) | VAF 45/174 reads (26%) | catalogued as rs751447894; called by muse, mutect2, varscan2
- RYR2 | c.7452C>G p.L2484= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- SALL3 | c.693C>A p.A231= | Silent (SNP) | VAF 56/170 reads (33%) | called by muse, mutect2, varscan2
- SCN4A | c.846C>G p.R282= | Silent (SNP) | VAF 95/342 reads (28%) | called by muse, mutect2, varscan2
- SHB | c.597C>T p.P199= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs780005330; called by muse, mutect2, varscan2
- SLC7A5 | c.984C>T p.P328= | Silent (SNP) | VAF 100/500 reads (20%) | catalogued as rs33936442; called by muse, mutect2, varscan2
- SLIT2 | c.3858G>A p.G1286= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- SLITRK1 | c.387G>A p.L129= | Silent (SNP) | VAF 91/525 reads (17%) | catalogued as rs1405853874, COSV100999946; called by muse, mutect2, varscan2
- ST8SIA5 | c.618G>A p.V206= | Silent (SNP) | VAF 23/237 reads (10%) | catalogued as COSV100164760; called by muse, mutect2, varscan2
- TFPI | c.174G>T p.A58= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV51900596; called by muse, mutect2, varscan2
- TKTL2 | c.135A>T p.A45= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- TMEM150B | c.75C>A p.A25= | Silent (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
- TNP2 | c.54C>T p.N18= | Silent (SNP) | VAF 45/295 reads (15%) | called by muse, mutect2, varscan2
- TNPO3 | c.462A>T p.V154= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2487G>T p.R829= | Silent (SNP) | VAF 309/715 reads (43%) | called by muse, varscan2
- TRPM3 | c.4548A>G p.L1516= (on ENST00000357533 / NM_001366142.2; = p.L1371= on NM_020952.6) | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.51975C>T p.I17325= (on ENST00000591111; = p.I9901= on NM_003319.4) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59910719; called by muse, mutect2, varscan2
- USP28 | c.3135G>A p.E1045= | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- VSX2 | c.246G>A p.G82= | Silent (SNP) | VAF 81/377 reads (21%) | catalogued as rs758201632; called by muse, mutect2, varscan2
- ZNF671 | c.603C>T p.F201= | Silent (SNP) | VAF 45/330 reads (14%) | called by muse, mutect2, varscan2
- ZZZ3 | c.1938C>G p.T646= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- ABTB1 | c.*83G>C | 3'UTR (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2327A>T | RNA (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3515C>G | RNA (SNP) | VAF 43/135 reads (32%) | catalogued as rs761509108; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83289G>T | Intron (SNP) | VAF 130/688 reads (19%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848535 C>A | 5'Flank (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- AL358334.1 | n.29-7394T>A | Intron (SNP) | VAF 77/322 reads (24%) | called by muse, varscan2
- AURKB | c.399-12C>G | Intron (SNP) | VAF 48/106 reads (45%) | called by muse, mutect2, varscan2
- C5orf17 | n.333C>T | RNA (SNP) | VAF 87/180 reads (48%) | catalogued as rs1322828628; called by muse, mutect2, varscan2
- CCDC74B | c.296-184G>A | Intron (SNP) | VAF 57/337 reads (17%) | catalogued as rs1431325472; called by muse, mutect2, varscan2
- CD8A | c.-51C>T | 5'UTR (SNP) | VAF 42/286 reads (15%) | called by muse, varscan2
- CDK18 | c.131-62del | Intron (DEL) | VAF 42/116 reads (36%) | catalogued as rs755289020; called by mutect2, pindel, varscan2
- CEP20 | c.-14G>T | 5'UTR (SNP) | VAF 74/267 reads (28%) | called by muse, mutect2, varscan2
- CFAP92 | c.*1G>A | 3'UTR (SNP) | VAF 59/163 reads (36%) | called by muse, mutect2, varscan2
- CFH | c.*26A>C | 3'UTR (SNP) | VAF 89/670 reads (13%) | called by muse, mutect2, varscan2
- CFL2 | c.*328A>T | 3'UTR (SNP) | VAF 444/809 reads (55%) | called by muse, mutect2, varscan2
- CLK2P1 | n.1080G>C | RNA (SNP) | VAF 206/717 reads (29%) | called by muse, mutect2, varscan2
- CPNE4 | chr3:132037627 del G | 5'Flank (DEL) | VAF 61/220 reads (28%) | called by mutect2, pindel, varscan2
- CPSF4 | c.103+2267G>T | Intron (SNP) | VAF 28/163 reads (17%) | called by muse, mutect2, varscan2
- DDX11 | c.638+995G>T | Intron (SNP) | VAF 101/324 reads (31%) | called by muse, mutect2, varscan2
- DUSP28 | c.394-38C>T | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs762131383; called by muse, mutect2
- EMBP1 | n.949C>T | RNA (SNP) | VAF 23/138 reads (17%) | called by muse, varscan2
- FAM167A | c.381+5962G>T | Intron (SNP) | VAF 18/64 reads (28%) | catalogued as rs973438009; called by muse, varscan2
- FOXP2 | c.*1537C>A | 3'UTR (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2463+1085G>C | Intron (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- GCSAML | c.-17C>A | 5'UTR (SNP) | VAF 151/268 reads (56%) | catalogued as COSV100825986, COSV63577061; called by muse, mutect2, varscan2
- KLRD1 | c.101-15A>T | Intron (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- LILRB1 | c.-308G>A | 5'UTR (SNP) | VAF 32/182 reads (18%) | catalogued as rs1168816468; called by muse, mutect2, varscan2
- LINC00692 | n.627T>C | RNA (SNP) | VAF 35/97 reads (36%) | called by muse, mutect2, varscan2
- LMOD1 | c.*1813A>G | 3'UTR (SNP) | VAF 45/544 reads (8%) | catalogued as rs1340747088; called by muse, mutect2
- MIR873 | n.13dup | RNA (INS) | VAF 32/85 reads (38%) | called by mutect2, pindel, varscan2
- NFATC3 | c.3107-11974A>G | Intron (SNP) | VAF 31/197 reads (16%) | called by muse, mutect2, varscan2
- NOL4L | c.-1T>A | 5'UTR (SNP) | VAF 36/129 reads (28%) | called by muse, mutect2, varscan2
- NPIPB14P | n.601G>T | RNA (SNP) | VAF 121/657 reads (18%) | catalogued as rs1396644626; called by muse, mutect2, varscan2
- NPR3 | chr5:32710721 A>T | 5'Flank (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- NTM-AS1 | n.2264G>T | RNA (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- OR10AB1P | n.1018G>T | RNA (SNP) | VAF 28/133 reads (21%) | called by muse, varscan2
- PCM1 | c.4109-2162G>T | Intron (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- PKD1L2 | n.598G>T | RNA (SNP) | VAF 40/286 reads (14%) | called by muse, mutect2
- POM121L4P | n.659G>T | RNA (SNP) | VAF 146/855 reads (17%) | called by muse, mutect2, varscan2
- PORCN | c.*45G>T | 3'UTR (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- PRSS40A | n.142-2300G>T | Intron (SNP) | VAF 73/501 reads (15%) | called by muse, mutect2, varscan2
- PTPRC | c.658+36C>A | Intron (SNP) | VAF 123/285 reads (43%) | catalogued as COSV61418971; called by muse, mutect2, varscan2
- RCAN1 | c.586+150C>T | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- REN | c.*45G>T | 3'UTR (SNP) | VAF 44/411 reads (11%) | called by muse, mutect2, varscan2
- RIN3 | c.250-993C>T | Intron (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42850963 T>A | 3'Flank (SNP) | VAF 47/221 reads (21%) | called by muse, mutect2, varscan2
- RPL10 | c.330-23G>A | Intron (SNP) | VAF 124/450 reads (28%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3929C>G | Intron (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- SCAMP2 | c.225+548G>T | Intron (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- SERINC2 | c.39+694del | Intron (DEL) | VAF 12/98 reads (12%) | catalogued as rs1393632740; called by mutect2, pindel, varscan2
- SLC2A2 | c.-13C>G | 5'UTR (SNP) | VAF 40/243 reads (16%) | catalogued as COSV100049172; called by muse, mutect2, varscan2
- SLC6A10P | n.3083C>T | RNA (SNP) | VAF 48/381 reads (13%) | called by muse, mutect2, varscan2
- STAG3L2 | n.1298C>T | RNA (SNP) | VAF 34/654 reads (5%) | called by muse, mutect2
- STAG3L2 | n.1297G>A | RNA (SNP) | VAF 34/647 reads (5%) | called by muse, mutect2
- TCF19 | chr6:31166277 C>T | 3'Flank (SNP) | VAF 26/188 reads (14%) | called by muse, mutect2, varscan2
- TCF4 | c.1637+33C>A | Intron (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- TRPC6 | c.-27G>T | 5'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, varscan2
- UGT3A1 | c.94+56del | Intron (DEL) | VAF 38/221 reads (17%) | called by mutect2, pindel, varscan2
- UQCRB | c.*3384G>T | 3'UTR (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- WASF4P | n.1221T>A | RNA (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- WT1 | chr11:32435781 C>A | 5'Flank (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- ZBTB7B | chr1:155010945 C>T | 5'Flank (SNP) | VAF 183/494 reads (37%) | catalogued as rs978961349; called by muse, mutect2, varscan2
- ZNF692 | c.1154-150C>A | Intron (SNP) | VAF 47/433 reads (11%) | catalogued as rs1339944124; called by muse, mutect2, varscan2
